Somatic mutation profile of tumor specimen 0DQSTX from CCDI case PBCFNK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 14.3 years (5,214 days).
Specimen 0DQSTX: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2d94341-e9f4-4fe7-b7e8-79a182104eed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQSUR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/676ebc8d-dcae-49cd-b3e4-525ef1f7a4e8

The open-access MAF lists 75 somatic variants for this specimen: 49 protein-altering or splice-affecting, 9 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Intron 10, Silent 9, In Frame Del 6, Frame Shift Del 3, Nonsense Mutation 3, 3'UTR 3, Frame Shift Ins 2, 5'Flank 2, 3'Flank 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 161/473 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.751A>T p.I251F | Missense Mutation (SNP) | VAF 140/342 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM114005, COSV52677403, COSV52702261, COSV52772679, COSV52927118; called by muse, mutect2, varscan2
- ANO7 | c.1480G>A p.A494T (on ENST00000274979; = p.A440T on NM_001370694.2) | Missense Mutation (SNP) | VAF 149/838 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.084); catalogued as rs182045324; called by muse, mutect2, varscan2
- ATP6V1H | c.1267C>T p.R423* | Nonsense Mutation (SNP) | VAF 132/665 reads (20%) | catalogued as rs1015333072; called by muse, mutect2, varscan2
- BACH2 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 52/554 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.024); catalogued as rs781265188; called by muse, mutect2, varscan2
- CCDC168 | c.3160G>T p.A1054S | Missense Mutation (SNP) | VAF 91/217 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as rs1193939827, COSV70555356; called by muse, mutect2, varscan2
- CHST8 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 166/669 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52861084; called by muse, mutect2, varscan2
- CSGALNACT1 | c.373C>T p.H125Y | Missense Mutation (SNP) | VAF 151/625 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as rs756494914; called by muse, mutect2, varscan2
- CTNNA2 | c.47G>T p.S16I | Missense Mutation (SNP) | VAF 73/472 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV63557917; called by muse, mutect2, varscan2
- EDRF1 | c.1413_1415del p.K471del (on ENST00000356792 / NM_001202438.2; = p.K437del on NM_015608.2) | In Frame Del (DEL) | VAF 78/358 reads (22%) | catalogued as rs773000225; called by pindel, varscan2
- EXT2 | c.1096C>T p.P366S (on ENST00000343631; = p.P399S on NM_000401.3) | Missense Mutation (SNP) | VAF 52/254 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.05); catalogued as COSV59149517; called by muse, mutect2, varscan2
- GRIK3 | c.1127G>C p.G376A | Missense Mutation (SNP) | VAF 46/917 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100901906, COSV66136884; called by muse, mutect2
- KIF4B | c.2356G>A p.E786K | Missense Mutation (SNP) | VAF 237/832 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as rs866289935; called by muse, mutect2, varscan2
- MCM3 | c.891del p.F297Lfs*43 (on ENST00000229854 / NM_001366374.2; = p.F287Lfs*43 on NM_002388.6 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 93/573 reads (16%) | catalogued as COSV57716607; called by mutect2, pindel, varscan2
- NLRP2 | c.2602C>T p.R868W | Missense Mutation (SNP) | VAF 120/458 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs754768995; called by muse, mutect2, varscan2
- OR2L13 | c.574T>C p.W192R | Missense Mutation (SNP) | VAF 103/590 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.034); catalogued as rs1054781105; called by muse, mutect2, varscan2
- OR4K15 | c.616C>A p.P206T (on ENST00000305051; = p.P182T on NM_001005486.1) | Missense Mutation (SNP) | VAF 89/423 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.571); catalogued as COSV59300378; called by mutect2, varscan2
- PDCD6IP | c.1393G>A p.D465N | Missense Mutation (SNP) | VAF 31/444 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs766371014, COSV100218480; called by muse, mutect2
- SLC7A8 | c.152-1G>A p.X51_splice | Splice Site (SNP) | VAF 84/330 reads (25%) | catalogued as rs758851428; called by muse, mutect2, varscan2
- SLIT1 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 96/626 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs778979915, COSV56595476; called by muse, mutect2, varscan2
- SYTL1 | c.762G>C p.Q254H (on ENST00000543823; = p.Q242H on NM_032872.3) | Missense Mutation (SNP) | VAF 82/448 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.326); catalogued as rs1301059728; called by muse, mutect2, varscan2
- ACTL6A | c.336A>T p.K112N | Missense Mutation (SNP) | VAF 113/451 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- ANKH | c.47T>C p.F16S | Missense Mutation (SNP) | VAF 107/404 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- ARFGAP2 | c.649_651del p.K217del | In Frame Del (DEL) | VAF 119/651 reads (18%) | called by pindel, varscan2
- ARHGAP21 | c.4025_4027del p.E1342del | In Frame Del (DEL) | VAF 99/588 reads (17%) | called by pindel, varscan2
- ATP2B1 | c.1319C>T p.T440M | Missense Mutation (SNP) | VAF 94/398 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BRAT1 | c.2278C>G p.Q760E | Missense Mutation (SNP) | VAF 65/376 reads (17%) | SIFT tolerated (0.83); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- BTNL2 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 132/572 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CFAP299 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 126/407 reads (31%) | called by muse, mutect2, varscan2
- CTSL | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 82/281 reads (29%) | called by muse, mutect2, varscan2
- DNAH9 | c.4426C>G p.Q1476E | Missense Mutation (SNP) | VAF 79/338 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EFNA4 | c.508_509del p.S170Wfs*73 | Frame Shift Del (DEL) | VAF 114/467 reads (24%) | called by pindel, varscan2
- FPGT-TNNI3K | c.1079G>C p.G360A | Missense Mutation (SNP) | VAF 94/402 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FRMPD3 | c.1438G>T p.A480S | Missense Mutation (SNP) | VAF 166/559 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- FUT4 | c.819_821del p.A277del | In Frame Del (DEL) | VAF 142/605 reads (23%) | called by mutect2, pindel, varscan2
- HMGXB4 | c.115G>C p.D39H | Missense Mutation (SNP) | VAF 15/516 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KLF4 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MGAT4B | c.433_435del p.V145del | In Frame Del (DEL) | VAF 104/506 reads (21%) | called by pindel, varscan2
- MOK | c.546G>C p.K182N | Missense Mutation (SNP) | VAF 201/890 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NET1 | c.205_206insT p.R69Lfs*6 | Frame Shift Ins (INS) | VAF 72/394 reads (18%) | called by mutect2, pindel, varscan2
- PSD | c.2186_2187del p.P729Qfs*43 | Frame Shift Del (DEL) | VAF 139/703 reads (20%) | called by mutect2, pindel, varscan2
- RGPD4 | c.1691G>C p.R564T | Missense Mutation (SNP) | VAF 220/1211 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SAP130 | c.3114dup p.V1039Sfs*26 | Frame Shift Ins (INS) | VAF 122/652 reads (19%) | called by mutect2, pindel, varscan2
- SCAP | c.1062_1064del p.V355del | In Frame Del (DEL) | VAF 39/264 reads (15%) | called by pindel, varscan2
- SLC22A1 | c.506T>G p.F169C | Missense Mutation (SNP) | VAF 119/586 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- SMARCA1 | c.397G>C p.D133H | Missense Mutation (SNP) | VAF 104/357 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- SUGP1 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 67/580 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- SYTL1 | c.81G>C p.E27D | Missense Mutation (SNP) | VAF 69/370 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZSWIM5 | c.3037C>A p.P1013T | Missense Mutation (SNP) | VAF 94/332 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.729); called by mutect2, varscan2
- CCDC88A | c.5436C>T p.A1812= (on ENST00000436346 / NM_001365480.1; = p.A1784= on NM_018084.5) | Silent (SNP) | VAF 129/653 reads (20%) | catalogued as rs771013322; called by muse, mutect2, varscan2
- DEPDC5 | c.1956C>G p.P652= (on ENST00000400246; = p.P730= on NM_001242896.3) | Silent (SNP) | VAF 141/377 reads (37%) | called by muse, mutect2, varscan2
- EPPK1 | c.5661G>A p.E1887= | Silent (SNP) | VAF 150/479 reads (31%) | catalogued as rs1205904982; called by muse, mutect2, varscan2
- GIGYF1 | c.2256C>T p.P752= | Silent (SNP) | VAF 158/571 reads (28%) | catalogued as rs749558916, COSV51943505; called by muse, mutect2, varscan2
- HTR2A | c.753G>C p.V251= | Silent (SNP) | VAF 126/264 reads (48%) | catalogued as COSV66328617; called by muse, mutect2, varscan2
- JPH1 | c.990A>G p.K330= | Silent (SNP) | VAF 68/341 reads (20%) | called by muse, mutect2, varscan2
- NR4A2 | c.1632G>A p.G544= | Silent (SNP) | VAF 90/436 reads (21%) | called by muse, mutect2, varscan2
- PIEZO2 | c.1146G>A p.A382= | Silent (SNP) | VAF 137/727 reads (19%) | catalogued as rs763345529; called by muse, mutect2, varscan2
- TRIM54 | c.378C>T p.C126= | Silent (SNP) | VAF 159/793 reads (20%) | catalogued as rs1251823596, COSV56081918; called by muse, mutect2, varscan2
- ABI2 | c.725+91T>A | Intron (SNP) | VAF 39/130 reads (30%) | catalogued as COSV99652400; called by muse, mutect2, varscan2
- AC013489.1 | c.*756-1924A>C | Intron (SNP) | VAF 26/96 reads (27%) | catalogued as rs778374354; called by muse, mutect2, varscan2
- AP5Z1 | c.1595+21G>T | Intron (SNP) | VAF 140/679 reads (21%) | called by muse, mutect2, varscan2
- CD33 | c.925-75C>A | Intron (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2, varscan2
- DENND4C | c.5740+98G>C | Intron (SNP) | VAF 8/112 reads (7%) | catalogued as COSV59548948; called by muse, mutect2
- EDA2R | c.*28C>A | 3'UTR (SNP) | VAF 45/295 reads (15%) | catalogued as COSV53632297; called by muse, mutect2, varscan2
- EFTUD2 | c.1286-68G>T | Intron (SNP) | VAF 56/175 reads (32%) | called by muse, mutect2, varscan2
- EGR2 | c.-82T>A | 5'UTR (SNP) | VAF 27/104 reads (26%) | called by muse, varscan2
- ENTPD8 | c.555+55G>A | Intron (SNP) | VAF 105/382 reads (27%) | called by muse, mutect2, varscan2
- GPR137 | chr11:64286413 G>A | 5'Flank (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2, varscan2
- MAGEB3 | c.*70G>T | 3'UTR (SNP) | VAF 55/87 reads (63%) | called by muse, mutect2, varscan2
- NUDT15 | chr13:48037696 G>A | 5'Flank (SNP) | VAF 34/67 reads (51%) | catalogued as rs113950881; called by muse, mutect2, varscan2
- OPTN | chr10:13136942 T>C | 3'Flank (SNP) | VAF 24/99 reads (24%) | catalogued as rs987265843; called by muse, mutect2, varscan2
- PGLS | c.288+686A>G | Intron (SNP) | VAF 37/193 reads (19%) | catalogued as rs929114206; called by muse, mutect2, varscan2
- RDH10 | c.771-64A>G | Intron (SNP) | VAF 37/151 reads (25%) | called by muse, mutect2, varscan2
- UBXN8 | c.88+25C>T | Intron (SNP) | VAF 33/184 reads (18%) | called by muse, mutect2, varscan2
- WDR70 | c.*2G>T | 3'UTR (SNP) | VAF 131/446 reads (29%) | called by muse, mutect2, varscan2
